Somatic mutation profile of tumor specimen TCGA-BR-7957-01A (aliquot TCGA-BR-7957-01A-11D-2201-08) from TCGA case TCGA-BR-7957, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 50.7 years (18,517 days).
Specimen TCGA-BR-7957-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1a05185-0f52-4027-b279-b7e59a311009.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7957-10A (Blood Derived Normal), aliquot TCGA-BR-7957-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae71fc00-07cc-466b-9f60-cd67d8de42ba

The open-access MAF lists 45 somatic variants for this specimen: 39 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 34, Silent 6, Nonsense Mutation 4, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 9/194 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2
- POLR1A | c.2527C>T p.R843* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as rs1377622831, COSV55693561; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANOS1 | c.289A>G p.R97G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV52920449; called by muse, mutect2
- AXIN2 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61057806; called by muse, mutect2
- BIRC6 | c.13861T>A p.Y4621N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70199715; called by muse, mutect2, varscan2
- BRINP1 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56301113; called by muse, mutect2, varscan2
- DSCAM | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs778085708, COSV68639793; called by mutect2, varscan2
- DST | c.446A>G p.E149G | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.046); catalogued as COSV56819837; called by muse, mutect2, varscan2
- DYTN | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV71752162; called by muse, mutect2
- ECM1 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV60873124; called by muse, mutect2, varscan2
- FAM214B | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.272); catalogued as rs745839514, COSV100521396; called by muse, mutect2, varscan2
- GALNT16 | c.1480A>G p.M494V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.072); catalogued as COSV61886171; called by muse, mutect2
- IMMP2L | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV59241624; called by muse, mutect2
- INPP5B | c.2093A>G p.Q698R (on ENST00000373023; = p.Q618R on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV65961031; called by muse, mutect2
- IQSEC2 | c.1489G>C p.E497Q (on ENST00000642864 / NM_001111125.3; = p.E292Q on NM_015075.2) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.852); catalogued as COSV64725687; called by muse, mutect2
- ITGA4 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1259352312, COSV52000576, COSV99276706; called by muse, mutect2, varscan2
- KDM4C | c.3058A>T p.R1020* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | catalogued as COSV67186983; called by muse, mutect2, varscan2
- NEK9 | c.1667G>A p.C556Y | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV53131161; called by muse, mutect2
- NOA1 | c.1313G>A p.R438K | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as COSV51737217; called by muse, mutect2, varscan2
- OR10H1 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771720675, COSV58470679; called by muse, mutect2, varscan2
- OR52N2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs147573020; called by muse, mutect2, varscan2
- PCDH19 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.272); catalogued as rs997198770, COSV55263780; called by muse, mutect2, varscan2
- PIGR | c.229A>T p.K77* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as COSV62904151; called by muse, mutect2
- PLCH1 | c.932C>T p.A311V (on ENST00000340059 / NM_001130960.2; = p.A323V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58190378, COSV58198473; called by muse, mutect2, varscan2
- PNMA8B | c.1071C>G p.I357M | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.699); catalogued as rs1292192552, COSV66536736; called by muse, mutect2, varscan2
- POU2F2 | c.1181G>T p.S394I (on ENST00000526816 / NM_001207025.3; = p.S378I on NM_002698.5) | Missense Mutation (SNP) | VAF 27/288 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV60763148; called by muse, mutect2
- RBBP7 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58112978; called by muse, mutect2, varscan2
- RIMBP2 | c.422C>G p.S141C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV55473457; called by muse, mutect2, varscan2
- SOX5 | c.2228A>T p.E743V | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV58630911; called by muse, mutect2, varscan2
- SYNE2 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200503488; called by muse, mutect2, varscan2
- SZT2 | c.7582C>T p.R2528C (on ENST00000634258 / NM_001365999.1; = p.R2471C on NM_015284.4) | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.292); catalogued as rs139028803; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SZT2 | c.9472C>T p.R3158* (on ENST00000634258 / NM_001365999.1; = p.R3101* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 10/136 reads (7%) | catalogued as rs1304526156, COSV65094621; called by muse, mutect2
- TSGA10IP | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs371057516, COSV73245387; called by muse, mutect2
- UPB1 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs765021908, COSV100387247; called by muse, mutect2, varscan2
- ZNF544 | c.2060C>A p.P687H | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54136140; called by muse, mutect2, varscan2
- ZNF808 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs780627649, COSV63120008; called by muse, mutect2
- ZNF835 | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV73379205; called by muse, mutect2
- IGLV1-40 | c.108G>C p.R36S | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDLIM5 | c.1089_1091dup p.Q364dup | In Frame Ins (INS) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- BPIFB4 | c.1068G>A p.G356= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs1276029703, COSV64951271; called by muse, mutect2, varscan2
- CNTROB | c.63A>C p.S21= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV58050309; called by muse, mutect2, varscan2
- HOOK2 | c.1572G>T p.L524= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV53402411; called by mutect2, varscan2
- KCNA1 | c.1104G>A p.V368= | Silent (SNP) | VAF 14/169 reads (8%) | catalogued as COSV66837443; called by muse, mutect2
- POTEH | c.96C>T p.F32= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as rs1295202371, COSV58880166; called by muse, mutect2, varscan2
- VIL1 | c.327C>G p.G109= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV50288535; called by muse, mutect2
